Gene-level copy-number profile of tumor specimen ALCH-AEUB-TTP1-A from ALCHEMIST case ALCH-AEUB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 76.2 years (27,825 days).
Specimen ALCH-AEUB-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6c46ed86-136b-4756-8abf-64a3f6c5e096.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEUB-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,757 have no estimate.
https://portal.gdc.cancer.gov/files/811d9e7b-39ba-4bba-82bf-8a7451b9476e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 325; copy number 1: 7,585; copy number 2: 48,203; copy number 3: 2,659; copy number 4: 80; copy number 7: 7; copy number 8: 5; copy number 9: 2.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:25,180,497–25,197,656, 10 genes (within-gene range 0–2): SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 14 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:34,784,028–36,191,194, 7 genes, copy number 7 (within-gene range 4–7): LINC01288, AC087343.1, UNC5D, AC090740.1, LSM12P1, AC105230.1, AC124290.1.
- chr11:1,947,278–2,001,470, 7 genes, copy number 8–9: MRPL23, MRPL23-AS1, LINC01219, H19, AC051649.3, MIR675, AC051649.2.

Autosomal genes at a single copy (total copy number 1): 5,081. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
